Somatic mutation profile of tumor specimen TCGA-NA-A4QY-01A (aliquot TCGA-NA-A4QY-01A-11D-A28R-08) from TCGA case TCGA-NA-A4QY, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mesodermal mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage III; Age at diagnosis: 62.3 years (22,756 days).
Specimen TCGA-NA-A4QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01bfaa3b-8abb-4538-b9d3-343383e12f42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NA-A4QY-10A (Blood Derived Normal), aliquot TCGA-NA-A4QY-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f487b2dd-4302-4768-a310-b04df22a7526

The open-access MAF lists 48 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 35, Silent 9, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 273/305 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs34569244; called by muse, mutect2, varscan2
- ARID1A | c.6191T>G p.L2064R | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61375233, COSV61376699; called by muse, mutect2, varscan2
- ARVCF | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as rs556096878, COSV52889556; called by muse, mutect2, varscan2
- BMP15 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); catalogued as rs782724245, COSV53140921; called by muse, mutect2, varscan2
- CRTC3 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs747306899; called by muse, mutect2, varscan2
- DST | c.17077G>A p.V5693I (on ENST00000361203 / NM_001374722.1; = p.V3390I on NM_015548.5) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.664); catalogued as COSV55004026; called by muse, mutect2, varscan2
- GRIK3 | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66140165; called by muse, mutect2
- GRM4 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.023); catalogued as rs756128186; called by muse, mutect2, varscan2
- HPCAL4 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.785); catalogued as rs1478857861, COSV100864765; called by muse, mutect2, varscan2
- HTT | c.7754C>T p.P2585L | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1297928308; called by muse, mutect2, varscan2
- INHBA | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54219953; called by muse, mutect2, varscan2
- KIAA1217 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.302); catalogued as COSV56820188; called by muse, mutect2, varscan2
- NAXD | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs781273519, COSV59395853; called by muse, mutect2, varscan2
- POTEF | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs776009831; called by muse, mutect2, varscan2
- SUPT6H | c.1652G>T p.R551L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV58932628; called by muse, mutect2, varscan2
- UNC5D | c.1592A>G p.Q531R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54776751; called by muse, mutect2, varscan2
- USP43 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs781145928; called by muse, mutect2, varscan2
- ZFAT | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs757186542, COSV64738202; called by muse, mutect2, varscan2
- ZNF808 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs758287539, COSV100708128, COSV100708315; called by muse, mutect2, varscan2
- ARID5A | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CCDC141 | c.1923T>G p.D641E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC181 | c.583T>A p.F195I | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLASP2 | c.4246A>T p.N1416Y (on ENST00000359576; = p.N1415Y on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CLTCL1 | c.3380C>G p.S1127C | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DOCK5 | c.1247A>T p.N416I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- EWSR1 | c.1654del p.L552Sfs*74 | Frame Shift Del (DEL) | VAF 78/229 reads (34%) | called by mutect2, pindel, varscan2
- KLHL25 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KMT5B | c.1477G>C p.D493H | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MET | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NECTIN2 | c.180_194del p.P61_I65del | In Frame Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- PGR | c.375dup p.Q126Afs*58 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- SEC11A | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SMC6 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TBL2 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM17 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRMT6 | c.1304T>G p.V435G | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- URB2 | c.111_112insG p.P38Afs*3 | Frame Shift Ins (INS) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- ZNF479 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CRHR1 | c.561C>A p.L187= (on ENST00000398285 / NM_001145146.2; = p.L158= on NM_004382.5) | Silent (SNP) | VAF 94/195 reads (48%) | called by muse, mutect2, varscan2
- DHX30 | c.2466A>G p.Q822= (on ENST00000445061 / NM_138615.3; = p.Q783= on NM_014966.3) | Silent (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- DNMBP | c.1914G>C p.V638= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- EGFLAM | c.2595C>T p.F865= (on ENST00000354891 / NM_001205301.2; = p.F857= on NM_152403.4) | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as rs368848352; called by muse, mutect2, varscan2
- MYOM3 | c.1308C>T p.G436= | Silent (SNP) | VAF 60/164 reads (37%) | called by muse, mutect2, varscan2
- NT5C1B | c.882G>A p.P294= (on ENST00000359846 / NM_001199086.2; = p.P234= on NM_033253.4) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs372417853; called by muse, mutect2, varscan2
- SAMD4B | c.1509C>T p.I503= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs887006494; called by muse, mutect2, varscan2
- SLC17A6 | c.1146G>A p.T382= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as rs117003321; called by muse, mutect2, varscan2
- SMAP1 | c.432T>A p.A144= | Silent (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
